Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17L-01A (Primary Tumor).

[page 1 of 5]
100-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

12/9/10

Site Code: Endometrium C54.1

Surgical Pathology

DIAGNOSIS:

A. Skin and subcutaneous tissue, abdomen, excision: Skin and subcutaneous tissue (2175 grams) with umbilicus identified grossly.

B. Uterus, left and right ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomies: FIGO grade I (of III) endometrial adenocarcinoma, endometrioid type arising in a background of complex hyperplasia with atypia is identified forming a mass (4.8 x 3.5 x 1.8 cm) located in the posterior/anterior uterine wall. The tumor invades 0.4 cm into the myometrium (total wall thickness, 1.8 cm in greatest dimension) and also involves adenomyosis. The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. There are multiple (2) intramural leiomyomata (ranging in size from 1.2 cm to 2.2 cm in greatest dimension). The bilateral ovaries and fallopian tubes are not involved.
[AJCCpT1bNOMX].

C. D. E. F. Lymph nodes, right pelvic, excision: Multiple right pelvic lymph nodes (1 internal iliac, 3 external iliac, 3 common iliac, and 9 obturator) are negative for tumor.

G. H. I. J. Lymph nodes, left pelvic, excision: Multiple left pelvic lymph nodes (2 internal iliac, 4 external iliac, 5 common iliac, and 7 obturator) are negative for tumor.

[page 2 of 5]
PRELIMINARY FROZEN SECTION CONSULTATION:

B. Uterus, left and right ovaries and fallopian tubes,
hysterectomy
and bilateral salpingo-oophorectomies: FIGO grade I (of
III)

endometrial adenocarcinoma, endometrioid type is
identified forming

a mass (4.8 x 3.5 x 1.8 cm) located in the
posterior/anterior
uterine wall. The tumor invades 0.5 cm into the
myometrium (total
wall thickness, 1.8 cm in greatest dimension).

A. Skin and subcutaneous tissue, abdomen, excision: Skin
and
subcutaneous tissue (2175 grams) with umbilicus identified
grossly.

C. D. E. F. Lymph nodes, right pelvic, excision:
Multiple right
pelvic lymph nodes (1 internal iliac, 3 external iliac, 3
common
iliac, and 9 obturator) are negative for tumor.

G. H. I. J. Lymph nodes, left pelvic, excision:
Multiple left
pelvic lymph nodes (2 internal iliac, 4 external iliac, 5
common
iliac, and 7 obturator) are negative for tumor.

GROSS DESCRIPTION:

A. Received fresh labeled "pannus" is a 2175 gram portion
of skin
and subcutaneous tissue, # umbilicus. No lesions
identified. Gross
Only.

B. Received fresh labeled "uterus, left and right tubes
and
ovaries" is a 130.0 gram uterus with attached bilateral
tubes and
ovaries and an unremarkable cervix. The uterine serosa is
smooth.

[page 3 of 5]
There is a 4.8 x 3.5 x 1.8 cm mass in the anterior/posterior fundus of the endometrial cavity invading 0.4 cm with 1.8 cm myometrial thickness. There are multiple (2) uterine intramural leiomyomas measuring 1.2 cm to 2.2 cm. There is a 3.1 x 1.5 x 1.1 cm right ovary with a smooth outer surface and a solid cut surface with a 9.0 x 0.5 cm right fallopian tube. There is a 3.8 x 2.5 x 1.0 cm left ovary with a smooth outer surface and a solid cut surface with an 8.1 x 0.5 cm left fallopian tube. Representative sections are submitted.

C. Received fresh labeled "right pelvic internal iliac" is a 3.0 x 2.0 x 0.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

D. Received fresh labeled "right pelvic external iliac" is a 3.0 x 2.5 x 0.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "right common iliac" is a 4.0 x 3.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

F. Received fresh labeled "right obturator" is an 8.0 x 3.5 x 1.2 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

G. Received fresh labeled "left pelvic internal iliac" is a 1.5 x 1.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 4 of 5]
H. Received fresh labeled "left pelvic external iliac" is a 4.5 x 3.0 x 1.5 cm aggregate of adipose and lymphatic tissue.

All lymphatic tissue submitted.

I. Received fresh labeled "left common iliac" is a 6.0 x 2.0 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

J. Received fresh labeled "left obturator" is a 6.5 x 2.5 x 1.4 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Pannus

Part B: Uterus, left and right tubes and ovaries

- 1 Endometrium mass-1
- 2 Endometrium mass-2
- 3 Lower uterine segment
- 4 Cervix 6:00
- 5 Right ovary
- 6 Rt fallopian tube
- 7 Left ovary
- 8 Lt fallopian tube
- 9 Myometrium nodule
- 10 Endometrium mass-3
- 11 Endometrium mass-4
- 12 Endometrium mass-5
- 13 Endometrium mass-6
- 14 Endometrium mass-7
- 15 Endometrium mass-8

Part C: Right Pelvic Lymph Nodes internal

- 1 Rt internal LNs 2 (C1)

Part D: Right Pelvic Lymph Nodes external

- 1 Rt external LNs 4 (D1)

Part E: Right Pelvic Lymph Nodes common

[page 5 of 5]
- 1 Rt common LNs 3 (E1)
- 2 Rt common LNs 1 (E2)
- 3 Rt common LNs 1 (E3)

Part F: Right Pelvic Lymph Nodes obturator

- 1 Rt obturator LNs 4 (F1)
- 2 Rt obturator LNs 1 (F2)
- 3 Rt obturator LNs 2 (F3)
- 4 Rt obturator LNs 1of6 (F4)
- 5 Rt obturator LNs 2of6 (F4)
- 6 Rt obturator LNs 3of6 (F4)
- 7 Rt obturator LNs 4of6 (F4)
- 8 Rt obturator LNs 5of6 (F4)
- 9 Rt obturator LNs 6of6 (F4)

Part G: Left Pelvic Lymph Nodes internal

- 1 Lt pelvic common LNs 1 (G1)

Part H: Left Pelvic Lymph Nodes external

- 1 Lt pelvic LNs 1of5 (H1)
- 2 Lt pelvic LNs 2of5 (H1)
- 3 Lt pelvic LNs 3of5 (H1)
- 4 Lt pelvic LNs 4of5 (H1)
- 5 Lt pelvic LNs 5of5 (H1)
- 6 Lt pelvic LNs 3 (H2)

Part I: Left Pelvic Lymph Nodes common

- 1 Lt pelvic common LNs 3 (I1)
- 2 Lt pelvic common LNs 2 (I2)

Part J: Left Pelvic Lymph Nodes obturator

- 1 Lt obturator LNs 4 (J1)
- 2 Lt obturator LNs 2 (J2)
- 3 Lt obturator LNs 2 (J3)
- 4 Lt obturator LNs 2 (J4)

Source: NCI Genomic Data Commons file 9735e32a-39c8-4cef-8b88-e67b9a87a0a4 (TCGA-D1-A17L.BCF17C02-8F6E-419F-AEDF-3AC03AA883E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).